Somatic mutation profile of tumor specimen TCGA-GU-AATQ-01A (aliquot TCGA-GU-AATQ-01A-11D-A391-08) from TCGA case TCGA-GU-AATQ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 69.0 years (25,185 days).
Specimen TCGA-GU-AATQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcc0e457-cfd7-48b3-9718-1ef8f575b81f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GU-AATQ-10A (Blood Derived Normal), aliquot TCGA-GU-AATQ-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3de9dac-3a91-4dd6-9e14-2b6c02d53287

The open-access MAF lists 192 somatic variants for this specimen: 139 protein-altering or splice-affecting, 45 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 45, Nonsense Mutation 15, RNA 3, Splice Site 3, 3'UTR 2, Splice Region 2, In Frame Del 1, Intron 1, 5'Flank 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 12/20 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FGFR3 | c.*108C>G | 3'UTR (SNP) | VAF 29/58 reads (50%) | catalogued as rs1057517964, CM084804, COSV53420509, COSV53421017; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- JUN | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 35/69 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1184098204, COSV64664188, COSV64664376; called by muse, mutect2, varscan2
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 23/33 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 27/63 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC11 | c.3299A>C p.E1100A | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62326061; called by muse, mutect2, varscan2
- ACSF2 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV51974304; called by muse, mutect2, varscan2
- ADAMTS17 | c.1300G>C p.D434H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV51494397; called by muse, mutect2, varscan2
- ALK | c.1495C>A p.P499T | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV66590528; called by muse, mutect2, varscan2
- ANKLE1 | c.874C>G p.P292A (on ENST00000394458; = p.P238A on NM_152363.6) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as rs867714566, COSV63921659; called by muse, mutect2, varscan2
- APLP1 | c.1213C>G p.Q405E | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV55707127; called by muse, mutect2, varscan2
- ARHGAP33 | c.2734C>G p.L912V | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); catalogued as COSV50170496; called by muse, mutect2, varscan2
- ARHGAP33 | c.2975C>G p.S992* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as rs1178196000, COSV99140268; called by muse, mutect2, varscan2
- ARHGAP33 | c.3077C>G p.S1026C | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV50170861; called by muse, mutect2, varscan2
- ARHGEF17 | c.834C>G p.D278E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as rs763776581, COSV55238535; called by muse, mutect2, varscan2
- ATP5MC2 | c.194C>G p.S65* | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | catalogued as COSV100101079; called by muse, varscan2
- ATXN1 | c.1426G>A p.G476S | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as rs776409489, COSV55232076; called by muse, mutect2, varscan2
- B4GALNT3 | c.2325C>A p.C775* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99843671; called by muse, mutect2, varscan2
- BAZ2A | c.4789G>A p.V1597I | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV51644202; called by muse, mutect2, varscan2
- BRCA1 | c.3628G>C p.E1210Q | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.852); catalogued as CD055641, COSV100524011, COSV58800485; called by muse, mutect2, varscan2
- C12orf45 | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV55013183; called by muse, mutect2, varscan2
- CDH3 | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50573469; called by muse, mutect2, varscan2
- CELF3 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs770229986, COSV51883458; called by muse, mutect2, varscan2
- CEND1 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs750922024, COSV57195136; called by muse, mutect2, varscan2
- CERS1 | c.303G>C p.E101D | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55930883; called by muse, mutect2, varscan2
- CHSY1 | c.1694T>C p.V565A | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.304); catalogued as COSV54256212; called by muse, mutect2, varscan2
- CSMD2 | c.8504G>T p.C2835F | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99596002; called by muse, mutect2
- CSMD3 | c.8281G>A p.E2761K (on ENST00000297405 / NM_001363185.1; = p.E2592K on NM_052900.3) | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.779); catalogued as COSV52327398; called by muse, mutect2, varscan2
- DBR1 | c.1462G>C p.D488H | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.188); catalogued as COSV53431258; called by muse, mutect2, varscan2
- DISP3 | c.1745C>T p.S582F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53833965; called by muse, mutect2, varscan2
- DNAH3 | c.4751C>T p.A1584V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs752783725, COSV54553969; called by muse, mutect2, varscan2
- DSG2 | c.1971G>A p.W657* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV99853592; called by muse, mutect2, varscan2
- DSG3 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV57129938, COSV99933873; called by muse, mutect2, varscan2
- ECT2 | c.920G>C p.R307T (on ENST00000392692 / NM_001349098.2; = p.R276T on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV51694591; called by muse, mutect2, varscan2
- ECT2 | c.1063G>A p.E355K (on ENST00000392692 / NM_001349098.2; = p.E324K on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.074); catalogued as COSV51694619; called by muse, mutect2, varscan2
- ELL3 | c.687G>C p.K229N | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55858460; called by muse, mutect2, varscan2
- EML2 | c.1042G>A p.G348R | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs746967055, COSV55598391; called by muse, mutect2, varscan2
- ERO1B | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs200824233, COSV51595368; called by muse, mutect2, varscan2
- ESRRG | c.716C>G p.S239* | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | catalogued as COSV100753985; called by muse, mutect2, varscan2
- EXOC2 | c.878A>G p.N293S | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs765662115, COSV57872181; called by muse, mutect2, varscan2
- FAM3D | c.70C>G p.R24G | Missense Mutation (SNP) | VAF 63/94 reads (67%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.646); catalogued as COSV62558796, COSV62559629; called by muse, mutect2, varscan2
- FRY | c.8487G>C p.Q2829H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.805); catalogued as COSV66511808; called by muse, mutect2, varscan2
- GABRQ | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 92/107 reads (86%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100941459, COSV64784033; called by muse, mutect2, varscan2
- GAPDH | c.892G>T p.G298W | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV57522148; called by muse, mutect2, varscan2
- GCAT | c.1108G>A p.G370S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1258805779, COSV50650361; called by muse, mutect2, varscan2
- GJD2 | c.10T>A p.W4R | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51750104; called by muse, mutect2, varscan2
- GLUD1 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 38/51 reads (75%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV53281460, COSV99517804; called by muse, mutect2, varscan2
- GOLGB1 | c.5642A>G p.D1881G | Missense Mutation (SNP) | VAF 72/248 reads (29%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.647); catalogued as rs760624768, COSV61467517; called by muse, mutect2, varscan2
- GPR171 | c.302C>G p.S101* | Nonsense Mutation (SNP) | VAF 31/126 reads (25%) | catalogued as rs1453793893, COSV56394513, COSV99854904; called by muse, mutect2, varscan2
- GRIA4 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV56881396, COSV56920966; called by muse, mutect2, varscan2
- GRIK1 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.879); catalogued as COSV58732893; called by muse, mutect2, varscan2
- GRIP1 | c.1366T>C p.S456P (on ENST00000359742 / NM_001379345.1; = p.S404P on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV54044315; called by muse, mutect2, varscan2
- HCRTR2 | c.45G>A p.W15* | Nonsense Mutation (SNP) | VAF 29/106 reads (27%) | catalogued as rs1198424252, COSV100904664; called by muse, mutect2, varscan2
- HSPBP1 | c.705G>C p.L235F | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.27); catalogued as COSV99729303; called by muse, mutect2, varscan2
- HTR3E | c.662G>C p.S221T (on ENST00000415389 / NM_001256613.1; = p.S236T on NM_182589.2) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV58949127; called by muse, mutect2, varscan2
- IARS1 | c.2124G>C p.E708D | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV65117248; called by muse, mutect2, varscan2
- IFT122 | c.1198C>T p.R400* (on ENST00000348417 / NM_052989.3; = p.R341* on NM_018262.4) | Nonsense Mutation (SNP) | VAF 20/118 reads (17%) | catalogued as rs369346055, COSV99959912; called by muse, mutect2, varscan2
- IL1R2 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60209724; called by muse, mutect2, varscan2
- INTS1 | c.2542C>G p.H848D | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.58); PolyPhen benign (0.062); catalogued as COSV67179885; called by muse, mutect2, varscan2
- INTS6 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV60880737; called by muse, mutect2, varscan2
- KBTBD2 | c.662G>C p.R221T | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58364378; called by muse, mutect2, varscan2
- KCNMB3 | c.45C>G p.S15R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as COSV62896060; called by mutect2, varscan2
- KCTD3 | c.2395C>G p.P799A | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); catalogued as rs766479624, COSV52070973; called by muse, mutect2, varscan2
- KRI1 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.557); catalogued as rs113565782, COSV57264632; called by muse, mutect2, varscan2
- KRT77 | c.1140G>A p.M380I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.101); catalogued as rs781520591, COSV59241613; called by muse, mutect2, varscan2
- LMNB2 | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.804); catalogued as COSV100322444; called by muse, mutect2
- LRRFIP1 | c.1840G>C p.E614Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57833906, COSV57834818; called by muse, mutect2, varscan2
- MAN2A1 | c.3043C>A p.H1015N | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.285); catalogued as rs1172976391, COSV54858895; called by muse, mutect2, varscan2
- MEF2D | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100560421, COSV61727227; called by muse, mutect2, varscan2
- MOGAT2 | c.238T>C p.W80R | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV52221490; called by muse, mutect2, varscan2
- MPP6 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV56036937, COSV56043313; called by muse, mutect2, varscan2
- MTTP | c.1738C>G p.Q580E | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV55504195; called by muse, mutect2, varscan2
- MYO3A | c.974A>C p.K325T | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV56350623; called by muse, mutect2
- MYO7B | c.6171G>C p.W2057C | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61442462, COSV61444979; called by muse, mutect2, varscan2
- NAT10 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as COSV57665437; called by muse, mutect2, varscan2
- NAT10 | c.2094G>C p.L698F | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV57663012, COSV57666429; called by muse, mutect2, varscan2
- NCKAP5 | c.2384A>G p.Y795C | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs370409499; called by muse, mutect2, varscan2
- NCOA2 | c.3868C>G p.R1290G | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as COSV51218998, COSV51223452; called by muse, mutect2, varscan2
- NELL2 | c.235C>G p.Q79E | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as COSV61586068; called by muse, mutect2, varscan2
- NFASC | c.2264C>G p.S755W (on ENST00000339876 / NM_001378329.1; = p.S751W on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58381110, COSV58383192; called by muse, mutect2, varscan2
- NOTCH2 | c.3240G>C p.Q1080H | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56707026; called by muse, mutect2
- NPAS4 | c.692C>A p.S231Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs770386876, COSV60649051; called by muse, mutect2, varscan2
- NPEPL1 | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs1468047995, COSV61940684; called by muse, mutect2, varscan2
- NR5A2 | c.754C>T p.H252Y (on ENST00000367362 / NM_205860.3; = p.H206Y on NM_003822.5) | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV52647918; called by muse, mutect2, varscan2
- NSUN7 | c.695C>G p.S232C | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV57276484; called by muse, varscan2
- NUP133 | c.1148C>G p.S383* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as rs781295006, COSV99773536; called by muse, mutect2, varscan2
- OR2G2 | c.124A>G p.I42V | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV60742394; called by muse, mutect2, varscan2
- P3H2 | c.886G>C p.G296R | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs774186462, COSV60028290; called by muse, mutect2, varscan2
- PACSIN2 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV99606754; called by muse, mutect2, varscan2
- PAH | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.374); catalogued as rs1439603624, COSV61020657; called by muse, mutect2, varscan2
- PCDHB2 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as rs1181323447, COSV50615862; called by muse, mutect2, varscan2
- PCDHB6 | c.2179G>C p.E727Q | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV50733989; called by muse, mutect2, varscan2
- PCDHGA11 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs751221129, COSV54027720; called by muse, mutect2, varscan2
- PCDHGC5 | c.1438G>C p.D480H | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52769269; called by muse, mutect2, varscan2
- PDCD6 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as rs372244838; called by muse, mutect2, varscan2
- PDGFC | c.315-1G>A p.X105_splice | Splice Site (SNP) | VAF 16/41 reads (39%) | catalogued as rs1231208003, COSV56855441; called by muse, mutect2, varscan2
- PHTF1 | c.412A>C p.M138L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as rs764542503, COSV63368925; called by muse, mutect2, varscan2
- PKHD1 | c.11665A>T p.K3889* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100945470; called by muse, mutect2, varscan2
- PKHD1L1 | c.7885G>A p.E2629K | Missense Mutation (SNP) | VAF 90/178 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.184); catalogued as COSV65753855; called by muse, mutect2, varscan2
- PKNOX2 | c.146C>G p.S49* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV53540402, COSV53556292; called by muse, mutect2, varscan2
- PNLDC1 | c.1003C>G p.H335D | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as COSV51708252; called by muse, mutect2, varscan2
- PRM2 | c.154C>A p.H52N | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.068); catalogued as COSV54113473, COSV54114038; called by muse, mutect2, varscan2
- PTPRK | c.4040C>T p.S1347F (on ENST00000368215 / NM_001291984.2; = p.S1348F on NM_002844.4) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63902028; called by muse, mutect2, varscan2
- PVALB | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs137928260, COSV53413338; called by muse, mutect2, varscan2
- RGS7 | c.1089G>A p.W363* | Nonsense Mutation (SNP) | VAF 40/103 reads (39%) | catalogued as COSV100464292, COSV100471289; called by muse, mutect2, varscan2
- RICTOR | c.3255C>A p.F1085L | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs763781910, COSV57131203; called by muse, mutect2, varscan2
- RRAGA | c.233G>C p.R78P | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV65844212; called by muse, mutect2, varscan2
- SAMM50 | c.1222+1G>A p.X408_splice | Splice Site (SNP) | VAF 16/37 reads (43%) | catalogued as COSV63110718; called by muse, mutect2, varscan2
- SEC16B | c.2348A>G p.Y783C | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.533); catalogued as COSV57630299; called by muse, mutect2, varscan2
- SERPINA11 | c.643G>C p.A215P | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58243406; called by muse, mutect2, varscan2
- SFRP4 | c.667A>T p.I223F | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV71412725; called by muse, mutect2, varscan2
- SLC25A27 | c.505C>A p.R169= | Splice Region (SNP) | VAF 14/49 reads (29%) | catalogued as COSV64927923, COSV64928648; called by muse, mutect2, varscan2
- SMC1A | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV59128808, COSV59132023; called by muse, mutect2, varscan2
- SMCHD1 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs199543594; called by muse, mutect2, varscan2
- SORBS2 | c.1310G>A p.R437K | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); catalogued as COSV53016160; called by muse, mutect2, varscan2
- SSPN | c.282C>G p.V94= | Splice Region (SNP) | VAF 76/197 reads (39%) | catalogued as COSV54382250; called by muse, mutect2, varscan2
- SYNE1 | c.5822G>A p.S1941N (on ENST00000367255 / NM_182961.4; = p.S1948N on NM_033071.3) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54904625, COSV55110253; called by muse, mutect2, varscan2
- TAF2 | c.3007G>T p.A1003S | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.047); catalogued as COSV65421350; called by muse, mutect2, varscan2
- TAOK2 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.142); catalogued as COSV54241365; called by muse, mutect2, varscan2
- TEX9 | c.264-2A>G p.X88_splice | Splice Site (SNP) | VAF 32/77 reads (42%) | catalogued as COSV61880710; called by muse, mutect2, varscan2
- THSD7A | c.4703G>A p.R1568K | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101349167, COSV68472333; called by muse, mutect2, varscan2
- TMEM67 | c.1801C>A p.P601T | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60044785; called by muse, mutect2, varscan2
- TNMD | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 14/18 reads (78%) | catalogued as COSV100887932; called by muse, mutect2, varscan2
- TRHDE | c.1792C>G p.P598A | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53867192; called by muse, mutect2, varscan2
- TRIO | c.6574G>C p.E2192Q | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV60096689; called by muse, mutect2, varscan2
- TSPOAP1 | c.2690C>T p.S897F | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52118400; called by muse, mutect2, varscan2
- UGP2 | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs1457689933, COSV61430406; called by muse, mutect2, varscan2
- VPS37C | c.6G>C p.E2D | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as COSV57110144; called by muse, mutect2, varscan2
- VWA3B | c.737T>C p.V246A | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV68247014; called by muse, mutect2, varscan2
- WASHC5 | c.1551T>A p.N517K | Missense Mutation (SNP) | VAF 53/86 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV59200734; called by muse, mutect2, varscan2
- WDR91 | c.1695C>G p.I565M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV60372065; called by muse, mutect2, varscan2
- XIRP2 | c.2367T>G p.H789Q (on ENST00000628543; = p.H964Q on NM_152381.6) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.009); catalogued as COSV54736108; called by muse, mutect2, varscan2
- ZFYVE26 | c.5785G>A p.E1929K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs773268804, COSV61333800; called by muse, mutect2, varscan2
- ZHX1 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV52879191; called by muse, mutect2, varscan2
- ZNF184 | c.2237G>C p.R746T | Missense Mutation (SNP) | VAF 63/109 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV53005826; called by muse, mutect2, varscan2
- ZNF45 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV54194830; called by muse, mutect2
- ZNF615 | c.837G>C p.Q279H | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV65032281, COSV65035080; called by muse, mutect2, varscan2
- ZNF761 | c.2129G>C p.R710T | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.662); catalogued as COSV100483504; called by muse, mutect2, varscan2
- CEP120 | c.1176_1178del p.P394del | In Frame Del (DEL) | VAF 22/51 reads (43%) | called by mutect2, pindel, varscan2
- KDM6A | c.820dup p.Q274Pfs*9 | Frame Shift Ins (INS) | VAF 49/86 reads (57%) | called by mutect2, pindel, varscan2
- AP3M2 | c.453G>A p.T151= | Silent (SNP) | VAF 46/122 reads (38%) | catalogued as rs141205851, COSV51529744; called by muse, mutect2, varscan2
- APP | c.2169G>T p.L723= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as COSV61005280; called by muse, mutect2, varscan2
- ARMC4 | c.1734C>T p.I578= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs1326553377, COSV59474614; called by muse, mutect2, varscan2
- CACNA1A | c.180A>G p.A60= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV64213030; called by muse, mutect2
- CAVIN1 | c.306C>T p.T102= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV63812811; called by muse, mutect2, varscan2
- CC2D1A | c.2544C>G p.L848= | Silent (SNP) | VAF 38/150 reads (25%) | catalogued as COSV54309955; called by muse, mutect2, varscan2
- CELF2 | c.300G>A p.Q100= (on ENST00000416382 / NM_001025077.3; = p.Q107= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV59977565; called by muse, mutect2, varscan2
- CEP170B | c.1230C>T p.F410= (on ENST00000453495; = p.F339= on NM_015005.3) | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs751471747, COSV69026722; called by muse, mutect2
- CNTN4 | c.115T>C p.L39= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV68593703; called by muse, mutect2, varscan2
- CNTN5 | c.3264C>T p.T1088= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1207217362, COSV54359547; called by muse, mutect2, varscan2
- FGFR3 | c.969C>A p.L323= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs1163078824, COSV53421007; called by muse, mutect2, varscan2
- FMNL3 | c.300G>A p.R100= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV53308029; called by muse, mutect2, varscan2
- GAPDH | c.891T>C p.A297= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV57522139; called by muse, mutect2, varscan2
- GP5 | c.300G>A p.L100= | Silent (SNP) | VAF 49/166 reads (30%) | catalogued as COSV55469805; called by muse, mutect2, varscan2
- GPR182 | c.576C>T p.I192= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV55627276; called by muse, mutect2, varscan2
- GTF2I | c.2625C>G p.L875= (on ENST00000573035 / NM_032999.4; = p.L834= on NM_001518.5) | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV100260036; called by muse, mutect2, varscan2
- H3-5 | c.108G>A p.V36= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs1273270205, COSV61188321; called by muse, mutect2, varscan2
- ISLR | c.1263C>T p.L421= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV51434385; called by muse, mutect2, varscan2
- ITGA2B | c.402C>G p.V134= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV99289317; called by muse, mutect2
- KRT73 | c.618G>A p.S206= | Silent (SNP) | VAF 42/80 reads (53%) | catalogued as rs139888404; called by muse, mutect2, varscan2
- NLRC4 | c.2932C>T p.L978= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV50874831; called by muse, mutect2, varscan2
- NOL11 | c.1386G>A p.T462= | Silent (SNP) | VAF 87/187 reads (47%) | catalogued as rs184371826, COSV53523729; called by muse, mutect2, varscan2
- OR4C6 | c.864G>A p.R288= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs1400490759, COSV58606450; called by muse, mutect2, varscan2
- OXGR1 | c.93C>G p.L31= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs769494011, COSV53658654; called by muse, mutect2, varscan2
- OXSR1 | c.301C>T p.L101= | Silent (SNP) | VAF 34/40 reads (85%) | catalogued as rs1391859833, COSV61260700; called by muse, varscan2
- OXSR1 | c.381C>G p.L127= | Silent (SNP) | VAF 44/64 reads (69%) | catalogued as COSV61260708; called by muse, varscan2
- PATE1 | c.165C>T p.F55= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV59824387, COSV59825542; called by muse, mutect2, varscan2
- PCDH10 | c.1002C>T p.G334= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV52104415; called by muse, mutect2, varscan2
- PKD1L1 | c.4134G>A p.V1378= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV56978935; called by muse, mutect2, varscan2
- PRDM2 | c.1086T>C p.C362= | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as COSV52456149; called by muse, mutect2, varscan2
- PTPRT | c.3708G>A p.L1236= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs1022904070, COSV62023932; called by muse, mutect2, varscan2
- PXDN | c.4344G>T p.V1448= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV99415105; called by muse, mutect2
- REEP4 | c.447G>A p.R149= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as rs765662861, COSV100098296; called by muse, varscan2
- RPRD1B | c.198C>T p.V66= | Silent (SNP) | VAF 41/75 reads (55%) | catalogued as rs753633602, COSV65034146; called by muse, mutect2, varscan2
- SEMA6C | c.489G>C p.L163= | Silent (SNP) | VAF 12/17 reads (71%) | catalogued as COSV59007983; called by muse, mutect2, varscan2
- SLC26A6 | c.1104G>C p.L368= | Silent (SNP) | VAF 65/76 reads (86%) | catalogued as COSV56575817; called by muse, mutect2, varscan2
- SLC6A20 | c.789C>T p.A263= | Silent (SNP) | VAF 29/40 reads (73%) | catalogued as COSV62072892; called by muse, mutect2, varscan2
- SLC9A5 | c.2604C>A p.L868= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV55365192; called by muse, mutect2, varscan2
- SLCO1A2 | c.750G>A p.L250= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV56611185; called by muse, mutect2, varscan2
- SYVN1 | c.162C>G p.V54= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV53697517; called by muse, mutect2, varscan2
- TGFBR1 | c.258T>C p.C86= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as rs1424666406, COSV66627065; called by muse, mutect2, varscan2
- TTN | c.77769G>T p.A25923= (on ENST00000591111; = p.A18499= on NM_003319.4) | Silent (SNP) | VAF 31/39 reads (79%) | catalogued as COSV60364697, COSV60382985; called by muse, mutect2, varscan2
- USP11 | c.45C>T p.F15= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV52094110; called by muse, mutect2, varscan2
- ZNF235 | c.405G>A p.K135= | Silent (SNP) | VAF 47/140 reads (34%) | catalogued as rs1296800351, COSV52158606; called by muse, mutect2, varscan2
- ZNF335 | c.2574G>A p.E858= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100533326, COSV59820454; called by muse, mutect2, varscan2
- AL133467.5 | chr14:95662634 C>T | 3'Flank (SNP) | VAF 35/86 reads (41%) | catalogued as rs1416293516; called by muse, mutect2, varscan2
- CCNQP1 | n.399C>T | RNA (SNP) | VAF 23/42 reads (55%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*4297C>G | 3'UTR (SNP) | VAF 25/66 reads (38%) | catalogued as COSV57075393; called by muse, mutect2, varscan2
- ECPAS | chr9:111484437 C>T | 5'Flank (SNP) | VAF 12/15 reads (80%) | catalogued as rs764596952, COSV52208338; called by muse, mutect2, varscan2
- GCNT2 | c.926-35073T>G | Intron (SNP) | VAF 14/52 reads (27%) | catalogued as COSV53944679; called by muse, mutect2, varscan2
- MIR409 | n.43C>A | RNA (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- ZNF658B | n.2054A>G | RNA (SNP) | VAF 92/151 reads (61%) | called by muse, mutect2, varscan2
